Gene-level copy-number profile of tumor specimen TCGA-ZQ-A9CR-01A from TCGA case TCGA-ZQ-A9CR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.7 years (29,107 days).
Specimen TCGA-ZQ-A9CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.39b8854d-b7e4-411c-bf69-57b23b86fbbd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZQ-A9CR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84a34861-0dce-4f89-bcea-b7f56d2e8b33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,903; copy number 2: 35,939; copy number 3: 14,357; copy number 4: 3,526; copy number 5: 2,774; copy number 6: 807; copy number 7: 14; copy number 8: 12; copy number 10: 92; copy number 12: 22; copy number 13: 8; copy number 14: 53; copy number 15: 15; copy number 16: 4; copy number 20: 48; copy number 22: 4; copy number 28: 33; copy number 30: 28; copy number 31: 114; copy number 66: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZQ-A9CR-01A-11D-A396-01): tumor purity 0.33, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,785,128–59,810,647, 11 genes (within-gene range 0–2): LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,077 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,471,452–75,240,770, 75 genes, copy number 6 (broad region; genes not listed).
- chr3:80,442,081–80,442,305, 1 gene, copy number 5: AC108740.1.
- chr5:58,198–5,320,304, 111 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:25,963,839–45,895,970, 296 genes, copy number 6 (broad region; genes not listed).
- chr6:41,026,895–45,377,953, 155 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:70,972–36,724,549, 646 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:53,655,508–57,837,046, 163 genes, copy number 31–66 (broad region; genes not listed).
- chr8:76,904,591–102,124,907, 416 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr8:102,864,271–103,002,424, 1 gene, copy number 10 (within-gene range 2–10): MAILR.
- chr8:102,923,371–104,589,024, 36 genes, copy number 10: RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2.
- chr8:104,699,479–104,703,555, 1 gene, copy number 10: AC012564.1.
- chr8:123,497,889–126,292,788, 53 genes, copy number 7–22: FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5.
- chr8:126,556,323–127,419,050, 1 gene, copy number 10 (within-gene range 3–13): PCAT1.
- chr8:126,671,522–130,017,129, 46 genes, copy number 8–13 (within-gene range 6–13): RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr8:130,069,541–130,163,127, 3 genes, copy number 12: RNU6-1255P, ASAP1-IT2, AC103725.1.
- chr9:119,935,053–125,143,528, 108 genes, copy number 5 (broad region; genes not listed).
- chr14:30,893,799–38,728,481, 142 genes, copy number 5–6 (broad region; genes not listed).
- chr16:28,341,434–31,332,892, 244 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:20,946,906–21,633,524, 11 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1.
- chr18:21,661,787–21,662,395, 1 gene, copy number 5: AC106037.2.
- chr18:21,704,957–21,870,953, 1 gene, copy number 28 (within-gene range 4–28): MIB1.
- chr18:21,793,883–27,247,188, 108 genes, copy number 20–30 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,517. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
